Somatic mutation profile of tumor specimen MMRF_1985_1_BM_CD138pos (aliquot MMRF_1985_1_BM_CD138pos_T1_KBS5U_L07270) from MMRF case MMRF_1985, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 52.6 years (19,221 days).
Specimen MMRF_1985_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 567e6dbf-97e8-4cd0-b89e-9c043a935bdd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1985_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1985_1_PB_Whole_C3_KBS5U_L07271; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7853d1b-3bf5-4ecc-be4a-3e267d60b6e8

The open-access MAF lists 104 somatic variants for this specimen: 42 protein-altering or splice-affecting, 14 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, 3'UTR 30, Silent 14, Intron 10, 5'Flank 4, Frame Shift Del 3, RNA 3, Nonsense Mutation 2, Splice Site 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 38/88 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ABCB9 | c.368C>T p.T123M | Missense Mutation (SNP) | VAF 56/119 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1240661251; called by muse, mutect2, varscan2
- ACSM2B | c.13C>T p.R5* | Nonsense Mutation (SNP) | VAF 39/145 reads (27%) | catalogued as rs745852481, COSV61657708; called by muse, mutect2, varscan2
- AGMO | c.1076C>T p.A359V | Missense Mutation (SNP) | VAF 132/238 reads (55%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs778710561, COSV61112665; called by muse, mutect2, varscan2
- ALKBH8 | c.1378C>T p.R460C | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as rs374943078; called by muse, mutect2, varscan2
- ATP13A1 | c.2252C>T p.P751L | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs1195036288, COSV99365989; called by muse, mutect2, varscan2
- CYP7A1 | c.1175A>T p.Q392L | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs779707560; called by muse, mutect2, varscan2
- DMRT3 | c.74G>T p.R25L | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1168619754, COSV51904746; called by muse, mutect2, varscan2
- FAM98C | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs200637370, COSV53039684; called by muse, mutect2, varscan2
- H1-4 | c.193G>C p.A65P | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs144396504, COSV56799828; called by muse, mutect2, varscan2
- KANK1 | c.2910_2913del p.N970Kfs*4 | Frame Shift Del (DEL) | VAF 78/290 reads (27%) | catalogued as rs759782885; called by mutect2, pindel, varscan2
- LAMA1 | c.2332G>A p.G778R | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs758289965, COSV67544886; called by muse, mutect2, varscan2
- LRRC37A3 | c.3916C>T p.R1306C | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.454); catalogued as rs377433713; called by muse, mutect2, varscan2
- PRSS3P1 | n.454+1G>A | Splice Site (SNP) | VAF 60/217 reads (28%) | catalogued as rs1251258796; called by muse, varscan2
- RIMBP2 | c.2846G>A p.R949H | Missense Mutation (SNP) | VAF 54/135 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs150099064; called by muse, mutect2, varscan2
- SKOR1 | c.1852G>A p.A618T | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs1400777205; called by muse, mutect2, varscan2
- SNX12 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV52146376; called by muse, mutect2, varscan2
- TRAJ54 | c.47T>C p.L16P | Missense Mutation (SNP) | VAF 15/33 reads (45%) | catalogued as rs935787754; called by muse, mutect2, varscan2
- ALG10B | c.267_269del p.V90del | In Frame Del (DEL) | VAF 72/182 reads (40%) | called by pindel, varscan2
- BCL2L10 | c.142G>A p.V48M | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CADM4 | c.640A>G p.T214A | Missense Mutation (SNP) | VAF 50/231 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CEBPZ | c.2325del p.S775Rfs*3 | Frame Shift Del (DEL) | VAF 4/23 reads (17%) | called by mutect2, pindel, varscan2
- CEP89 | c.1904G>T p.G635V | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DGKK | c.2234G>T p.R745M | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- EPB41L3 | c.2312A>G p.E771G | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- FAM13C | c.759C>A p.D253E | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IGHV1-69D | c.127G>C p.A43P | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.235); called by muse, mutect2
- IGHV2-70D | c.69G>T p.L23F | Missense Mutation (SNP) | VAF 33/40 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IL4 | c.22C>T p.L8F | Missense Mutation (SNP) | VAF 197/656 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- KNTC1 | c.2558_2559del p.E853Gfs*13 | Frame Shift Del (DEL) | VAF 24/72 reads (33%) | called by pindel, varscan2
- L3MBTL4 | c.1386G>T p.Q462H | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- NSL1 | c.174A>T p.Q58H | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- PIP4K2B | c.323A>G p.E108G | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2
- RERG | c.548C>A p.T183N | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SCNN1D | c.524C>T p.S175F (on ENST00000338555; = p.S339F on NM_001130413.4) | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SNX20 | c.224A>C p.K75T | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- TSR2 | c.220A>T p.T74S | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- UCK1 | c.142G>C p.G48R | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- UGGT2 | c.1813G>A p.A605T | Missense Mutation (SNP) | VAF 30/44 reads (68%) | SIFT tolerated (0.18); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- YIPF1 | c.139T>G p.S47A | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZCWPW1 | c.1468A>T p.R490* | Nonsense Mutation (SNP) | VAF 83/147 reads (56%) | called by muse, mutect2, varscan2
- ZFHX4 | c.7759G>C p.D2587H | Missense Mutation (SNP) | VAF 81/191 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- AC090517.4 | c.453T>C p.S151= | Silent (SNP) | VAF 37/178 reads (21%) | called by muse, mutect2, varscan2
- ADAMTSL3 | c.3978C>G p.V1326= | Silent (SNP) | VAF 19/73 reads (26%) | called by muse, mutect2, varscan2
- CCDC171 | c.1644T>A p.S548= | Silent (SNP) | VAF 23/102 reads (23%) | called by muse, mutect2, varscan2
- CLASP2 | c.606G>A p.V202= | Silent (SNP) | VAF 59/253 reads (23%) | called by muse, mutect2, varscan2
- DIS3L2 | c.2235G>A p.A745= | Silent (SNP) | VAF 51/126 reads (40%) | catalogued as rs751938833; ClinVar: likely benign; called by muse, mutect2, varscan2
- GAPVD1 | c.2718A>C p.V906= (on ENST00000394104; = p.V933= on NM_015635.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 78/244 reads (32%) | catalogued as COSV52924054; called by muse, mutect2, varscan2
- IGHV2-70 | c.210A>C p.A70= | Silent (SNP) | VAF 36/88 reads (41%) | catalogued as rs61732229; called by muse, varscan2
- IGHV2-70D | c.342T>C p.Y114= | Silent (SNP) | VAF 15/25 reads (60%) | catalogued as rs1178804456; called by muse, varscan2
- IGLV3-25 | c.67C>T p.L23= | Silent (SNP) | VAF 21/35 reads (60%) | catalogued as rs369721805; called by muse, varscan2
- KCNC1 | c.564C>T p.Y188= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as rs1404328793; called by muse, mutect2, varscan2
- P2RY10 | c.841C>A p.R281= | Silent (SNP) | VAF 117/289 reads (40%) | catalogued as COSV50680374, COSV99409376; called by muse, mutect2, varscan2
- PCDHGA4 | c.891C>T p.A297= | Silent (SNP) | VAF 53/233 reads (23%) | called by muse, mutect2, varscan2
- PLPP5 | c.450T>C p.S150= | Silent (SNP) | VAF 71/111 reads (64%) | called by muse, mutect2, varscan2
- QRFPR | c.135G>A p.K45= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as COSV57676849; called by muse, mutect2, varscan2
- AC068473.1 | n.579T>C | RNA (SNP) | VAF 55/206 reads (27%) | called by muse, mutect2, varscan2
- AC073254.1 | n.1132-1662C>T | Intron (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- AFTPH | c.*105A>G | 3'UTR (SNP) | VAF 38/94 reads (40%) | called by muse, varscan2
- AL359922.1 | c.348-35062G>A | Intron (SNP) | VAF 47/166 reads (28%) | catalogued as rs750053305, COSV64268912; called by muse, mutect2, varscan2
- AMMECR1 | c.*2969A>C | 3'UTR (SNP) | VAF 26/55 reads (47%) | called by muse, mutect2, varscan2
- BEND5 | c.*294T>A | 3'UTR (SNP) | VAF 6/130 reads (5%) | called by muse, mutect2
- BX664718.2 | n.966A>G | RNA (SNP) | VAF 59/172 reads (34%) | catalogued as rs891825337; called by muse, mutect2, varscan2
- C1orf43 | c.*685G>T | 3'UTR (SNP) | VAF 25/55 reads (45%) | called by muse, mutect2, varscan2
- CARMIL2 | c.3743-14G>T | Intron (SNP) | VAF 24/55 reads (44%) | catalogued as COSV54669931; called by muse, mutect2, varscan2
- CEACAM18 | c.-14A>G | 5'UTR (SNP) | VAF 30/122 reads (25%) | catalogued as rs1432297812; called by muse, mutect2, varscan2
- DIPK1C | c.*557G>C | 3'UTR (SNP) | VAF 34/128 reads (27%) | called by muse, mutect2, varscan2
- DNLZ | c.*72G>A | 3'UTR (SNP) | VAF 7/35 reads (20%) | catalogued as rs371364979, COSV52517069; called by muse, mutect2, varscan2
- DUSP22 | c.435+95A>G | Intron (SNP) | VAF 30/125 reads (24%) | called by muse, mutect2, varscan2
- ELMOD2 | c.*1473A>T | 3'UTR (SNP) | VAF 24/84 reads (29%) | called by muse, mutect2, varscan2
- ERBB4 | c.*2216A>C | 3'UTR (SNP) | VAF 44/108 reads (41%) | called by muse, mutect2, varscan2
- FOXN2 | c.*3797G>A | 3'UTR (SNP) | VAF 21/53 reads (40%) | called by muse, mutect2, varscan2
- GCOM2 | n.254G>A | RNA (SNP) | VAF 31/82 reads (38%) | called by muse, mutect2, varscan2
- GMFB | c.*434T>G | 3'UTR (SNP) | VAF 19/43 reads (44%) | called by muse, mutect2, varscan2
- HSPA13 | c.*899C>T | 3'UTR (SNP) | VAF 57/111 reads (51%) | called by muse, mutect2, varscan2
- IHO1 | c.532+773A>G | Intron (SNP) | VAF 18/50 reads (36%) | called by muse, mutect2, varscan2
- IPP | c.*279C>T | 3'UTR (SNP) | VAF 22/68 reads (32%) | called by muse, mutect2, varscan2
- KHNYN | c.*2660A>G | 3'UTR (SNP) | VAF 19/48 reads (40%) | called by muse, mutect2, varscan2
- LOXL3 | c.*1083T>C | 3'UTR (SNP) | VAF 19/43 reads (44%) | catalogued as rs1204099658; called by muse, mutect2, varscan2
- MBIP | c.*199C>T | 3'UTR (SNP) | VAF 41/85 reads (48%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851265 T>C | 5'Flank (SNP) | VAF 49/126 reads (39%) | catalogued as rs193097634; called by muse, varscan2
- MIR5195 | chr14:106851340 T>G | 5'Flank (SNP) | VAF 53/110 reads (48%) | called by muse, varscan2
- NACC2 | c.*4291T>C | 3'UTR (SNP) | VAF 141/510 reads (28%) | catalogued as rs983620511; called by muse, mutect2, varscan2
- NIPAL3 | c.*192G>A | 3'UTR (SNP) | VAF 20/42 reads (48%) | called by muse, mutect2, varscan2
- OSBPL9 | c.*610T>C | 3'UTR (SNP) | VAF 31/88 reads (35%) | called by muse, mutect2, varscan2
- PANK3 | c.*7627A>G | 3'UTR (SNP) | VAF 15/68 reads (22%) | called by muse, mutect2, varscan2
- PGM2L1 | c.*2260T>C | 3'UTR (SNP) | VAF 40/147 reads (27%) | catalogued as rs1565432099; called by muse, mutect2, varscan2
- PLEKHG7 | c.530+393T>C | Intron (SNP) | VAF 24/70 reads (34%) | called by muse, mutect2, varscan2
- PLK4 | c.223-40T>C | Intron (SNP) | VAF 29/77 reads (38%) | called by muse, mutect2, varscan2
- RAB9B | c.*168A>T | 3'UTR (SNP) | VAF 24/65 reads (37%) | called by muse, mutect2
- RAB9B | c.*166T>A | 3'UTR (SNP) | VAF 25/68 reads (37%) | catalogued as rs1356452380; called by muse, mutect2
- RCHY1 | c.*1185T>G | 3'UTR (SNP) | VAF 4/82 reads (5%) | called by muse, mutect2
- REXO4 | c.*717C>A | 3'UTR (SNP) | VAF 23/87 reads (26%) | called by muse, mutect2, varscan2
- RGMA | c.130+6778G>A | Intron (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2, varscan2
- SCIN | c.*860dup | 3'UTR (INS) | VAF 20/56 reads (36%) | catalogued as rs987110392; called by mutect2, varscan2
- SKIDA1 | c.*688A>T | 3'UTR (SNP) | VAF 45/106 reads (42%) | called by muse, mutect2, varscan2
- SPANXN1 | c.*80A>C | 3'UTR (SNP) | VAF 55/180 reads (31%) | called by muse, mutect2, varscan2
- SRPK3 | chrX:153779511 T>A | 5'Flank (SNP) | VAF 9/21 reads (43%) | called by muse, mutect2, varscan2
- SRPK3 | chrX:153780292 T>C | 5'Flank (SNP) | VAF 26/65 reads (40%) | called by muse, mutect2, varscan2
- SULT4A1 | c.*1226G>A | 3'UTR (SNP) | VAF 38/69 reads (55%) | called by muse, mutect2, varscan2
- TLCD4 | c.*2804C>G | 3'UTR (SNP) | VAF 26/64 reads (41%) | called by muse, mutect2, varscan2
- TLE4 | c.390+115T>C | Intron (SNP) | VAF 40/107 reads (37%) | called by muse, mutect2, varscan2
- TMEM44 | c.612+243T>C | Intron (SNP) | VAF 38/116 reads (33%) | called by muse, mutect2, varscan2
- ZFP62 | c.*503G>A | 3'UTR (SNP) | VAF 52/198 reads (26%) | called by muse, mutect2, varscan2
